Somatic mutation profile of tumor specimen TCGA-06-5410-01A (aliquot TCGA-06-5410-01A-01D-1696-08) from TCGA case TCGA-06-5410, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.3 years (26,395 days).
Specimen TCGA-06-5410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 677eb0e0-4801-4635-9893-5c4a96ac809b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5410-10A (Blood Derived Normal), aliquot TCGA-06-5410-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/490001eb-233e-4f34-a1a9-85c7f1d2c5b0

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHEX | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 7/123 reads (6%) | catalogued as rs1556030502; ClinVar: pathogenic; called by muse, mutect2
- CYP3A5 | c.557G>C p.G186A | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs962504304, COSV56118697; called by muse, mutect2
- EIF2S3 | c.69G>A p.L23= | Splice Region (SNP) | VAF 10/116 reads (9%) | catalogued as COSV53405935; called by muse, mutect2
- FREM2 | c.4724T>G p.V1575G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV54829791; called by muse, mutect2
- GRM3 | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141671463; called by muse, mutect2
- KCTD16 | c.1157A>C p.K386T | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.813); catalogued as COSV72576866; called by muse, mutect2, varscan2
- LRFN5 | c.1429G>C p.A477P | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53244532; called by muse, mutect2
- LY75 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55102318; called by muse, mutect2
- NF1 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 15/163 reads (9%) | catalogued as CM143319, COSV62194044, COSV62197904; called by muse, mutect2
- OR8H2 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs779838445, COSV57943323; called by muse, mutect2
- PIP | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs776666213, COSV52120017; called by muse, mutect2
- PORCN | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs782505896, CM109530, COSV58225577; called by muse, mutect2
- SI | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV52267375; called by muse, mutect2
- WNK3 | c.2614C>T p.R872* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV63612282; called by muse, mutect2
- ZNF263 | c.1049A>G p.E350G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV54595354; called by muse, mutect2, varscan2
- BCL2L14 | c.162C>T p.S54= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV53783859; called by muse, mutect2
- C1orf112 | c.237C>T p.S79= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV53676897; called by muse, mutect2
- GLYATL2 | c.696C>T p.Y232= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1432608551, COSV54849092; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1975C>T p.L659= | Silent (SNP) | VAF 11/145 reads (8%) | catalogued as COSV61144087; called by muse, mutect2
- ZBED1 | c.1299G>A p.T433= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as rs772761841, COSV58130855; called by muse, mutect2
